Somatic mutation profile of tumor specimen TCGA-27-1831-01A (aliquot TCGA-27-1831-01A-01D-1494-08) from TCGA case TCGA-27-1831, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.9 years (24,447 days).
Specimen TCGA-27-1831-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dd57f7-a2a2-48fc-b7d4-a54eb961ec99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1831-10A (Blood Derived Normal), aliquot TCGA-27-1831-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd58f0a1-0534-485c-8e8b-4dd02b591e46

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Nonsense Mutation 4, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 1985/4614 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); catalogued as COSV63488090; called by muse, mutect2
- APOB | c.11824G>A p.A3942T | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1265296445, COSV51940990; called by muse, mutect2, varscan2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CDCP1 | c.1738G>A p.V580M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs773715040, COSV56106338, COSV56106516; called by muse, mutect2, varscan2
- CEP126 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142032267, COSV54826164; called by muse, mutect2, varscan2
- COL14A1 | c.2847G>T p.R949S | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52858802; called by muse, varscan2
- DAO | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140015394; called by muse, mutect2, varscan2
- EBF3 | c.1266C>G p.I422M (on ENST00000355311 / NM_001375392.1; = p.I413M on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV62476836; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 275/7310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2
- EPHA8 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs769624500, COSV51274070; called by muse, mutect2, varscan2
- EPYC | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 97/293 reads (33%) | catalogued as rs374036301, COSV99664717; called by muse, mutect2, varscan2
- FAT2 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377056065; called by muse, mutect2, varscan2
- GPR83 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145628763, COSV54717571; called by muse, mutect2, varscan2
- IFNE | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 144/281 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV58642144; called by muse, mutect2, varscan2
- IL3RA | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs200665918, COSV58431795; called by muse, mutect2, varscan2
- KCNS3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.133); catalogued as COSV58407727; called by muse, mutect2, varscan2
- MUC16 | c.3983C>T p.T1328M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs1261277009, COSV67475867; called by muse, mutect2, varscan2
- MYO1D | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780229350, COSV59011313; called by muse, mutect2, varscan2
- NLRP3 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV60226917; called by muse, mutect2, varscan2
- NR1H4 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV51849062; called by muse, mutect2, varscan2
- NRCAM | c.2301G>T p.W767C (on ENST00000379028 / NM_001371124.1; = p.W751C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61040539; called by muse, mutect2, varscan2
- OIT3 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.985); catalogued as rs779208918, COSV61826522; called by muse, mutect2, varscan2
- OR52J3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774802089, COSV66747273; called by muse, mutect2, varscan2
- PDCL2 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs200093988, COSV55261237; called by muse, mutect2
- PPBP | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV56019956; called by muse, mutect2, varscan2
- PTPRM | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 123/385 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV59866599; called by muse, mutect2, varscan2
- RAB3D | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 102/339 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs144965675, COSV55791749; called by muse, mutect2, varscan2
- RELN | c.5015G>A p.C1672Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59012332; called by muse, mutect2, varscan2
- RPGRIP1 | c.2330C>A p.T777N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52851897; called by muse, mutect2, varscan2
- SDK1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs776052768, COSV67356197; called by muse, mutect2, varscan2
- SERPINE1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as rs760569885, COSV56169742; called by muse, mutect2, varscan2
- SLC9C2 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.249); catalogued as COSV62946659; called by muse, mutect2, varscan2
- SSTR4 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs368872232, COSV54798287; called by muse, mutect2, varscan2
- TANC2 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs372829353; called by muse, mutect2, varscan2
- TMEM196 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1328050808, COSV68254865; called by muse, mutect2, varscan2
- UBE3C | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 107/444 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV61954185; called by muse, mutect2, varscan2
- USH2A | c.9950G>A p.R3317H | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs140746096; called by muse, mutect2, varscan2
- USP6 | c.2347C>T p.Q783* | Nonsense Mutation (SNP) | VAF 16/196 reads (8%) | catalogued as COSV51486264; called by muse, mutect2
- WFS1 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV56989825; called by muse, mutect2, varscan2
- WWC2 | c.616dup p.M206Nfs*9 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | catalogued as rs760401865; called by mutect2, varscan2
- ZNF3 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 56/245 reads (23%) | catalogued as COSV52796105; called by muse, mutect2, varscan2
- ZNF91 | c.2474C>G p.P825R | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56085334, COSV56086529; called by muse, mutect2, varscan2
- OR10H2 | c.736_745dup p.V249Afs*27 | Frame Shift Ins (INS) | VAF 40/176 reads (23%) | called by mutect2, varscan2
- RIMS2 | c.3151A>T p.R1051* (on ENST00000666250 / NM_001348490.2; = p.R859* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- SATL1 | c.1298del p.V433Afs*8 (on ENST00000395409; = p.V620Afs*63 on NM_001012980.2) | Frame Shift Del (DEL) | VAF 60/120 reads (50%) | called by mutect2, pindel, varscan2
- FAM71F1 | c.138G>A p.P46= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as rs758275371, COSV59373399; called by muse, mutect2, varscan2
- GRIN2B | c.3819G>A p.T1273= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1555101910, COSV74206518; ClinVar: likely benign; called by muse, mutect2, varscan2
- HTR1D | c.642C>T p.I214= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV58448451; called by muse, mutect2, varscan2
- LOXL1 | c.1275C>T p.R425= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs368632424; called by muse, mutect2, varscan2
- NYAP2 | c.1386G>A p.S462= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs755401706, COSV56009290; called by muse, mutect2
- PYGM | c.1383C>T p.S461= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs775978754, COSV51220029; called by muse, mutect2, varscan2
- RYR2 | c.9351C>T p.F3117= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs773455753, COSV63693694; ClinVar: likely benign; called by muse, mutect2
- SPATA31A1 | c.1203T>C p.P401= | Silent (SNP) | VAF 75/359 reads (21%) | called by muse, mutect2, varscan2
- TLR6 | c.372G>A p.R124= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV67935447; called by muse, mutect2, varscan2
- TSPY2 | c.447C>T p.G149= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs756320520; called by muse, varscan2
- TTC29 | c.576C>T p.Y192= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs777478027, COSV57272500; called by muse, mutect2, varscan2
- SLC37A3 | c.*82C>G | 3'UTR (SNP) | VAF 34/202 reads (17%) | called by muse, mutect2, varscan2
